Somatic mutation profile of tumor specimen MP2PRT-PASZMD-TMP1-A (aliquot MP2PRT-PASZMD-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PASZMD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,435 days).
Specimen MP2PRT-PASZMD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fc85ede-ff34-401e-a87e-54ca549b751c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZMD-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZMD-NM1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9994e67f-bde5-4b19-af7e-96f52ab6cf9a

The open-access MAF lists 51 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 10, Nonsense Mutation 6, 5'Flank 1, Frame Shift Ins 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.4124C>T p.S1375L (on ENST00000272895 / NM_173076.3; = p.S1057L on NM_015657.3) | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs770633067; called by muse, mutect2, varscan2
- ATAD5 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.877); catalogued as COSV58977882; called by muse, mutect2, varscan2
- CYP4F12 | c.512C>A p.A171E | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1410591833; called by muse, mutect2, varscan2
- FAM135B | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 78/470 reads (17%) | catalogued as COSV50526390; called by muse, mutect2, varscan2
- FAM81B | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs933952692, COSV51984896, COSV51986183; called by muse, mutect2
- IKZF1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 93/630 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.136); catalogued as COSV58785613, COSV58788959; called by muse, mutect2, varscan2
- KIZ | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs11553176; called by muse, varscan2
- LGI3 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 75/464 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV60443259; called by muse, mutect2, varscan2
- NAA35 | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.093); catalogued as COSV64485719; called by muse, mutect2, varscan2
- NF1 | c.5501C>T p.S1834L (on ENST00000358273 / NM_001042492.3; = p.S1813L on NM_000267.3) | Missense Mutation (SNP) | VAF 71/554 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV62202653; called by muse, mutect2, varscan2
- PROB1 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 74/559 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs1339027467; called by muse, mutect2, varscan2
- SLC10A2 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 64/412 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs147515410; called by muse, varscan2
- SLC20A2 | c.1622G>C p.G541A | Missense Mutation (SNP) | VAF 66/505 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs780720351; called by muse, mutect2, varscan2
- SLC25A29 | c.523C>G p.L175V (on ENST00000359232 / NM_001039355.3; = p.L109V on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/592 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV63650447; called by muse, mutect2, varscan2
- SLC30A1 | c.490C>G p.R164G | Missense Mutation (SNP) | VAF 87/653 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV65360857; called by muse, mutect2, varscan2
- AGR3 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- AHDC1 | c.3577G>T p.E1193* | Nonsense Mutation (SNP) | VAF 88/461 reads (19%) | called by muse, mutect2, varscan2
- AHDC1 | c.2106G>C p.K702N | Missense Mutation (SNP) | VAF 122/624 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- DEPDC5 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DNAH12 | c.6877A>T p.R2293* (on ENST00000351747; = p.R2312* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 32/225 reads (14%) | called by muse, mutect2, varscan2
- FAM210A | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 104/378 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- GABRR1 | c.1068C>A p.F356L | Missense Mutation (SNP) | VAF 100/481 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- IFI35 | c.483G>C p.K161N (on ENST00000415816 / NM_001330230.2; = p.K163N on NM_005533.5) | Missense Mutation (SNP) | VAF 42/391 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- IMPG1 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 26/260 reads (10%) | called by muse, mutect2, varscan2
- MUC16 | c.32032G>A p.E10678K | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NAV3 | c.1253C>G p.S418C | Missense Mutation (SNP) | VAF 59/347 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- PABPC5 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 105/298 reads (35%) | called by muse, mutect2, varscan2
- PABPC5 | c.1079A>G p.E360G | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- PCSK5 | c.5410G>A p.E1804K | Missense Mutation (SNP) | VAF 62/503 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLSCR4 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 38/528 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- PTAR1 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- RAB35 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SALL3 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SKIDA1 | c.2501G>A p.S834N | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TBL1XR1 | c.423_424insCCCC p.A142Pfs*4 | Frame Shift Ins (INS) | VAF 30/247 reads (12%) | called by mutect2, pindel, varscan2
- UBA2 | c.579C>T p.F193= | Splice Region (SNP) | VAF 52/245 reads (21%) | called by muse, mutect2, varscan2
- UTP20 | c.5509G>A p.E1837K | Missense Mutation (SNP) | VAF 48/345 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- WSCD2 | c.1360G>C p.V454L | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZNF197 | c.2974G>T p.E992* | Nonsense Mutation (SNP) | VAF 18/482 reads (4%) | called by muse, mutect2
- ATG4B | c.933G>A p.A311= | Silent (SNP) | VAF 94/508 reads (19%) | catalogued as rs773033178; called by muse, mutect2, varscan2
- DCUN1D3 | c.285C>T p.F95= | Silent (SNP) | VAF 15/436 reads (3%) | called by muse, mutect2
- GRIA2 | c.1377C>T p.F459= | Silent (SNP) | VAF 62/447 reads (14%) | catalogued as rs748979507, COSV99643147; called by muse, mutect2, varscan2
- HS3ST2 | c.1008G>A p.Q336= | Silent (SNP) | VAF 58/482 reads (12%) | called by muse, varscan2
- NLRP2 | c.3081C>G p.L1027= | Silent (SNP) | VAF 43/331 reads (13%) | called by muse, mutect2, varscan2
- PTK2 | c.1968G>A p.T656= | Silent (SNP) | VAF 62/636 reads (10%) | catalogued as rs776101894, COSV100569374; called by muse, mutect2
- RASGRP2 | c.828C>A p.L276= | Silent (SNP) | VAF 61/319 reads (19%) | called by muse, mutect2, varscan2
- SMG7 | c.2448G>A p.V816= | Silent (SNP) | VAF 56/430 reads (13%) | called by muse, varscan2
- ZFP37 | c.627G>A p.K209= | Silent (SNP) | VAF 66/378 reads (17%) | called by muse, mutect2, varscan2
- ZNF131 | c.1113G>A p.L371= (on ENST00000509156 / NM_001330707.2; = p.L337= on NM_003432.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 47/445 reads (11%) | catalogued as rs780805881; called by muse, mutect2, varscan2
- ANKRD13C | chr1:70355147 G>A | 5'Flank (SNP) | VAF 61/470 reads (13%) | called by muse, mutect2, varscan2
- YWHAH | c.87+5563G>A | Intron (SNP) | VAF 67/360 reads (19%) | catalogued as rs772681878; called by muse, mutect2, varscan2
